Somatic mutation profile of tumor specimen TCGA-12-0829-01A (aliquot TCGA-12-0829-01A-01W-0424-08) from TCGA case TCGA-12-0829, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.2 years (27,471 days).
Specimen TCGA-12-0829-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d975a43-9d0d-4bca-b7cc-cce26f0be66d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-0829-10A (Blood Derived Normal), aliquot TCGA-12-0829-10A-01W-0424-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbcb4dfc-b83d-4752-befc-f39e0cec02ba

The open-access MAF lists 168 somatic variants for this specimen: 121 protein-altering or splice-affecting, 42 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 42, Frame Shift Del 9, Nonsense Mutation 8, In Frame Del 3, Intron 3, Splice Site 2, Splice Region 2, Frame Shift Ins 2, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH5 | c.9502C>T p.R3168* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as rs863224504, COSV54214334; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IMPG1 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 75/180 reads (42%) | catalogued as rs200651043, COSV64054288; ClinVar: likely pathogenic; called by muse, varscan2
- PLOD2 | c.1501-971dup | Intron (INS) | VAF 4/42 reads (10%) | catalogued as rs749709000; ClinVar: pathogenic; called by pindel, varscan2
- RAB3GAP1 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as rs532964185, CM133223, COSV99921697; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.950A>G p.H317R | Missense Mutation (SNP) | VAF 72/392 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.036); catalogued as rs764619906, COSV100879497; called by muse, varscan2
- AC008397.2 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.715); catalogued as rs1165436106, COSV99442213; called by muse, mutect2
- AC008397.2 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV53207085; called by muse, mutect2, varscan2
- ADGRB1 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as COSV100030269; called by muse, mutect2, varscan2
- AGMO | c.529C>G p.L177V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs1177367994, COSV100694670, COSV100695034; called by muse, mutect2, varscan2
- ALDH6A1 | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 88/549 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100620959; called by muse, mutect2, varscan2
- ARMCX1 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 9/262 reads (3%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.952); catalogued as COSV100863237; called by muse, mutect2
- ATAD2 | c.4099C>T p.R1367C | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1180402683, COSV54877158; called by muse, mutect2
- BCAS1 | c.72+1G>A p.X24_splice | Splice Site (SNP) | VAF 33/229 reads (14%) | catalogued as COSV101006427; called by muse, mutect2, varscan2
- BPIFB2 | c.1054T>G p.F352V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as COSV99401654; called by muse, mutect2, varscan2
- CASP6 | c.634G>C p.V212L | Missense Mutation (SNP) | VAF 256/1124 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV99488842; called by muse, varscan2
- CEP250 | c.2731C>T p.Q911* | Nonsense Mutation (SNP) | VAF 21/106 reads (20%) | catalogued as COSV100699171; called by muse, mutect2, varscan2
- CHRNA7 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 62/291 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100181712; called by muse, mutect2, varscan2
- CNGA1 | c.1381A>T p.I461F | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100652333; called by muse, mutect2, varscan2
- COL11A2 | c.4559G>A p.R1520H (on ENST00000341947 / NM_080680.3; = p.R1413H on NM_080679.2) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as rs772567850, COSV100554476; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPNE6 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 212/958 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV53747096; called by muse, varscan2
- CRYBG3 | c.6200C>T p.S2067L | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99477425; called by muse, mutect2
- CSF1R | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99642939; called by muse, mutect2
- CTNNA3 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 34/990 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101051466; called by muse, mutect2
- DDX56 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99346236; called by muse, mutect2, varscan2
- DNAH2 | c.8612C>T p.S2871L | Missense Mutation (SNP) | VAF 90/185 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs768853669, COSV101209571; called by mutect2, varscan2
- DOCK5 | c.3580G>A p.A1194T | Missense Mutation (SNP) | VAF 68/2020 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs186151980, COSV52399677; called by muse, mutect2
- DYNC1H1 | c.5263C>T p.Q1755* | Nonsense Mutation (SNP) | VAF 19/105 reads (18%) | catalogued as COSV100794755, COSV100795352; called by muse, mutect2
- EFHC1 | c.1916C>T p.S639L | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV100932139; called by muse, mutect2, varscan2
- EGFR | c.1934C>G p.S645C | Missense Mutation (SNP) | VAF 571/754 reads (76%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.982); catalogued as rs772046081, COSV51772147; called by muse, mutect2, varscan2
- ELMO1 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as rs923829225, COSV60294021, COSV60297204; called by muse, mutect2, varscan2
- ERVW-1 | c.948_949del p.R317Sfs*56 | Frame Shift Del (DEL) | VAF 15/116 reads (13%) | catalogued as rs748572132; called by mutect2, pindel, varscan2
- FBXW11 | c.1456C>A p.R486S | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.235); catalogued as COSV99441334, COSV99441425; called by muse, mutect2, varscan2
- FLG2 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101166180; called by muse, mutect2
- GALNT17 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as rs778395109, COSV61168313; called by muse, mutect2, varscan2
- GDF6 | c.396C>A p.D132E | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99748516; called by muse, mutect2
- GRIN2D | c.1536G>T p.K512N | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54379722, COSV99616909; called by muse, mutect2
- HRNR | c.3290G>C p.G1097A | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.711); catalogued as COSV100913892; called by muse, mutect2
- ICA1L | c.86T>A p.V29D | Missense Mutation (SNP) | VAF 96/194 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100841885; called by muse, mutect2, varscan2
- INTS1 | c.1428C>T p.F476= | Splice Region (SNP) | VAF 20/71 reads (28%) | catalogued as COSV101248292; called by muse, varscan2
- KARS1 | c.106A>G p.K36E | Missense Mutation (SNP) | VAF 136/881 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs1222836544, COSV100094503; called by muse, varscan2
- KCNH6 | c.2039G>A p.C680Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1203222614; called by mutect2, varscan2
- KRT74 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99977679; called by muse, mutect2, varscan2
- KRTAP15-1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV100481657; called by muse, mutect2, varscan2
- LIPH | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.317); catalogued as rs370653261; called by mutect2, varscan2
- MAGEC1 | c.2512A>T p.T838S | Missense Mutation (SNP) | VAF 250/282 reads (89%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0.299); catalogued as COSV99596445; called by mutect2, varscan2
- MUC16 | c.2557T>C p.S853P | Missense Mutation (SNP) | VAF 86/312 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); catalogued as COSV101200784; called by mutect2, varscan2
- MYH2 | c.4331C>T p.A1444V | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); catalogued as COSV99820884; called by muse, mutect2, varscan2
- NUP35 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.123); catalogued as COSV99717927; called by muse, mutect2, varscan2
- OPN5 | c.675G>T p.K225N | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV99790027; called by muse, mutect2
- OR1J2 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 54/293 reads (18%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs767716131, COSV100093143, COSV58945687; called by muse, mutect2, varscan2
- OR5H14 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs867052972, COSV101454051; called by muse, mutect2, varscan2
- OR5W2 | c.704T>C p.F235S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV100747739; called by muse, mutect2, varscan2
- PARP2 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 29/487 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99163044; called by muse, mutect2
- PCDHA2 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.654); catalogued as rs377636774, COSV65367219; called by mutect2, varscan2
- PHKB | c.2131C>A p.Q711K | Missense Mutation (SNP) | VAF 113/1166 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100068406; called by muse, mutect2, varscan2
- PHLPP2 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 56/673 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV100673424, COSV100673808; called by muse, mutect2
- PIK3CG | c.638A>C p.K213T | Missense Mutation (SNP) | VAF 134/234 reads (57%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV100783149, COSV63251366; called by mutect2, varscan2
- PLCB3 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 33/45 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99657710; called by muse, mutect2, varscan2
- PLEKHG3 | c.2157A>T p.R719S (on ENST00000394691; = p.R775S on NM_001308147.2) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.939); catalogued as COSV99907068; called by mutect2, varscan2
- PLVAP | c.47dup p.S17Qfs*106 | Frame Shift Ins (INS) | VAF 9/76 reads (12%) | catalogued as rs768884250; called by mutect2, pindel
- POLR3A | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1378974410, COSV100965792; called by muse, varscan2
- PTPRE | c.207C>T p.F69= | Splice Region (SNP) | VAF 14/268 reads (5%) | catalogued as COSV54549425; called by muse, mutect2
- PTPRT | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs866253502, COSV61998098; called by mutect2, varscan2
- RIOK1 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV99344905; called by muse, mutect2, varscan2
- RIPK2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55134550; called by muse, mutect2, varscan2
- RNF25 | c.863G>A p.S288N | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99829201; called by muse, mutect2
- ROR1 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 20/347 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV100935570; called by muse, mutect2
- RPL22 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV99329931; called by muse, mutect2
- RPN2 | c.1679G>T p.W560L | Missense Mutation (SNP) | VAF 26/704 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99412012; called by muse, mutect2
- SCTR | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778244105, COSV50028412; called by muse, mutect2, varscan2
- SDCCAG8 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100654589; called by muse, mutect2
- SENP5 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100052256; called by muse, mutect2, varscan2
- SIGLEC11 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs376315578, COSV101389619; called by muse, varscan2
- SLC6A3 | c.941C>T p.A314V | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747783826, CM143017, COSV54366657; called by muse, mutect2, varscan2
- SLF1 | c.2122-1G>A p.X708_splice | Splice Site (SNP) | VAF 13/48 reads (27%) | catalogued as COSV99475884, COSV99476273; called by muse, mutect2, varscan2
- SREK1 | c.1148G>A p.R383K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99398768; called by muse, mutect2, varscan2
- SRGAP3 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1475567613, COSV64540988; called by muse, mutect2, varscan2
- SRRT | c.86G>T p.R29I | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99566866; called by muse, mutect2
- STK17B | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV55827440, COSV99826294; called by muse, varscan2
- STRN4 | c.1534G>T p.D512Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99624011; called by muse, mutect2, varscan2
- SULF2 | c.2002C>T p.H668Y | Missense Mutation (SNP) | VAF 69/348 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100737424; called by muse, mutect2, varscan2
- SUPT6H | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 66/78 reads (85%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.019); catalogued as rs746505120, COSV58928879; called by muse, mutect2, varscan2
- TAFA4 | c.218C>T p.T73M | Missense Mutation (SNP) | VAF 213/276 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201735936; called by muse, mutect2, varscan2
- TECPR2 | c.1060A>T p.R354W | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV100850196, COSV63970376; called by mutect2, varscan2
- THSD4 | c.1880C>T p.T627I | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99966929; called by muse, mutect2, varscan2
- TKFC | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99582669; called by muse, mutect2, varscan2
- TTN | c.98398A>G p.T32800A (on ENST00000591111; = p.T25376A on NM_003319.4) | Missense Mutation (SNP) | VAF 74/755 reads (10%) | PolyPhen benign (0.048); catalogued as COSV100628106; called by muse, mutect2
- UMOD | c.1477G>A p.G493R | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as rs770533587, COSV100208655; called by muse, mutect2, varscan2
- UNC13B | c.2285G>T p.G762V | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101037257; called by muse, mutect2, varscan2
- UNC5C | c.2631G>T p.R877S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.993); catalogued as COSV71661415; called by muse, varscan2
- WDR91 | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100615830; called by muse, mutect2, varscan2
- XAB2 | c.2035G>A p.G679R | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400545894, COSV99351898; called by mutect2, varscan2
- ZNF254 | c.1712A>T p.E571V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100741765; called by muse, varscan2
- ZNF418 | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 189/1626 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV101268994; called by muse, varscan2
- ZNF808 | c.1256T>G p.I419R | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100708179; called by muse, mutect2
- ANKRD50 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); called by mutect2, varscan2
- BCAR1 | c.993dup p.A332Rfs*9 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- CAMTA1 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- CANX | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); called by mutect2, varscan2
- CAPN2 | c.1361T>C p.L454P | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- CATSPERD | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- CD163 | c.1589del p.G530Efs*30 | Frame Shift Del (DEL) | VAF 11/83 reads (13%) | called by mutect2, pindel, varscan2
- CYP3A43 | c.351_353del p.L118del | In Frame Del (DEL) | VAF 30/302 reads (10%) | called by mutect2, pindel
- ELF4 | c.1805C>T p.P602L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.098); called by mutect2, varscan2
- FLG2 | c.2260_2261del p.Q754Ifs*8 | Frame Shift Del (DEL) | VAF 28/200 reads (14%) | called by mutect2, pindel, varscan2
- IQSEC3 | c.1809del p.T604Pfs*22 (on ENST00000538872 / NM_001170738.2; = p.T301Pfs*22 on NM_015232.1) | Frame Shift Del (DEL) | VAF 11/19 reads (58%) | called by mutect2, varscan2
- LPIN2 | c.1207A>G p.I403V | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- MST1R | c.1472T>G p.L491R | Missense Mutation (SNP) | VAF 134/968 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- MUC16 | c.33426_33429del p.T11143Ffs*9 | Frame Shift Del (DEL) | VAF 148/855 reads (17%) | called by pindel, varscan2
- PON3 | c.465_471del p.K156* | Frame Shift Del (DEL) | VAF 36/146 reads (25%) | called by mutect2, varscan2*
- RUSC1 | c.783T>G p.N261K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by mutect2, varscan2
- SLC39A5 | c.947G>A p.R316K | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, varscan2
- TK1 | c.655A>G p.R219G | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.156); called by mutect2, varscan2
- TM7SF3 | c.707_708del p.A236Efs*2 | Frame Shift Del (DEL) | VAF 33/216 reads (15%) | called by mutect2, pindel, varscan2
- TMIGD3 | c.645_647del p.I216del (on ENST00000369717 / NM_001081976.2; = p.I297del on NM_020683.7) | In Frame Del (DEL) | VAF 21/72 reads (29%) | called by pindel, varscan2
- TRIM25 | c.1003A>G p.K335E | Missense Mutation (SNP) | VAF 444/1736 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.155); called by mutect2, varscan2
- TRMT12 | c.329del p.E110Gfs*2 | Frame Shift Del (DEL) | VAF 25/130 reads (19%) | called by mutect2, pindel, varscan2
- TTN | c.88639G>A p.A29547T (on ENST00000591111; = p.A22123T on NM_003319.4) | Missense Mutation (SNP) | VAF 130/566 reads (23%) | PolyPhen probably damaging (0.998); called by mutect2, varscan2
- UBC | c.371_381del p.K124Rfs*7 | Frame Shift Del (DEL) | VAF 224/568 reads (39%) | called by pindel, varscan2
- UBQLNL | c.453T>G p.F151L | Missense Mutation (SNP) | VAF 42/431 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- ZNF460 | c.871_897del p.Y291_N299del | In Frame Del (DEL) | VAF 734/2395 reads (31%) | called by mutect2*, pindel
- ZNF546 | c.2423A>G p.K808R | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ACACB | c.867C>T p.N289= | Silent (SNP) | VAF 360/817 reads (44%) | catalogued as rs150967404, COSV100623260; called by muse, mutect2, varscan2
- ADGRG4 | c.6418C>T p.L2140= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV99794588, COSV99796599; called by muse, mutect2, varscan2
- ARID1A | c.1293G>A p.P431= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs760630354, COSV61384836; called by muse, mutect2
- AXL | c.897C>T p.L299= | Silent (SNP) | VAF 180/644 reads (28%) | catalogued as COSV99997176; called by muse, varscan2
- BAZ1A | c.2787A>C p.I929= | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as COSV62410436; called by mutect2, varscan2
- BRIP1 | c.1920C>T p.I640= | Silent (SNP) | VAF 10/215 reads (5%) | catalogued as COSV51998263, COSV99370948; called by muse, mutect2
- CA12 | c.801C>A p.P267= | Silent (SNP) | VAF 21/279 reads (8%) | called by mutect2, varscan2
- CAMTA1 | c.1200C>T p.F400= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as COSV100352257; called by muse, mutect2, varscan2
- CDC6 | c.771G>A p.R257= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV99266674; called by muse, mutect2, varscan2
- CHRD | c.2562G>A p.S854= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs370030836; called by muse, mutect2, varscan2
- COLEC12 | c.543G>A p.L181= | Silent (SNP) | VAF 15/193 reads (8%) | catalogued as COSV101232159; called by muse, mutect2
- CUX1 | c.1542A>T p.T514= | Silent (SNP) | VAF 33/202 reads (16%) | called by mutect2, varscan2
- CYLD | c.2130A>G p.Q710= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100282737; called by muse, mutect2, varscan2
- DSC1 | c.2572C>T p.L858= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV57144658, COSV99938230; called by muse, varscan2
- FAT2 | c.10413C>T p.N3471= | Silent (SNP) | VAF 1974/2008 reads (98%) | catalogued as rs369724133; called by muse, varscan2
- FLNA | c.6777C>T p.F2259= (on ENST00000369850 / NM_001110556.2; = p.F2251= on NM_001456.3) | Silent (SNP) | VAF 70/82 reads (85%) | catalogued as COSV100775193, COSV61036478; called by muse, mutect2, varscan2
- FLNC | c.276C>T p.F92= | Silent (SNP) | VAF 130/340 reads (38%) | catalogued as rs774796561, COSV100368684; called by mutect2, varscan2
- HIPK4 | c.462C>T p.V154= | Silent (SNP) | VAF 24/308 reads (8%) | catalogued as COSV99397026; called by muse, mutect2
- LAMA2 | c.6771C>T p.P2257= | Silent (SNP) | VAF 677/2696 reads (25%) | catalogued as COSV101370805; called by muse, mutect2, varscan2
- LRP1 | c.8127C>T p.I2709= | Silent (SNP) | VAF 32/320 reads (10%) | catalogued as rs370209579; called by muse, mutect2, varscan2
- LRRK1 | c.4935G>A p.A1645= | Silent (SNP) | VAF 177/1290 reads (14%) | catalogued as rs150351638, COSV99442898; called by muse, mutect2, varscan2
- MCF2 | c.370C>T p.L124= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV100645113; called by muse, mutect2
- MRPL19 | c.636C>T p.N212= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100718966; called by muse, mutect2, varscan2
- MUC16 | c.2053C>T p.L685= | Silent (SNP) | VAF 223/481 reads (46%) | catalogued as rs1486622536, COSV101201421; called by muse, mutect2, varscan2
- NKRF | c.1365G>A p.L455= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100441873; called by mutect2, varscan2
- NPHS2 | c.372C>T p.C124= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs139290621, CM077330; called by muse, mutect2, varscan2
- P4HA2 | c.1416G>A p.L472= | Silent (SNP) | VAF 12/387 reads (3%) | catalogued as COSV51324791, COSV99387414; called by muse, mutect2
- PLCL1 | c.2724C>T p.I908= | Silent (SNP) | VAF 70/357 reads (20%) | catalogued as rs770703280, COSV70851136; called by muse, mutect2, varscan2
- PLVAP | c.336C>T p.I112= | Silent (SNP) | VAF 146/334 reads (44%) | catalogued as COSV53086123, COSV53087600, COSV99391819; called by muse, mutect2, varscan2
- SENP5 | c.174G>A p.Q58= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs750844771, COSV100052253; called by muse, varscan2
- SLC26A5 | c.789C>T p.G263= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100100098; called by muse, mutect2, varscan2
- SLC4A10 | c.1152C>T p.Y384= (on ENST00000446997 / NM_001354461.2; = p.Y354= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99765585; called by mutect2, varscan2
- SLC6A11 | c.1452C>T p.C484= | Silent (SNP) | VAF 162/1258 reads (13%) | catalogued as COSV99594966; called by muse, mutect2, varscan2
- SOAT2 | c.543G>A p.P181= | Silent (SNP) | VAF 36/44 reads (82%) | catalogued as rs151267658; called by muse, mutect2, varscan2
- THEG | c.930G>A p.S310= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as rs749985714, COSV61073512; called by muse, mutect2, varscan2
- TLR1 | c.1749C>T p.I583= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs776860609, COSV58306228; called by mutect2, varscan2
- TRIM28 | c.1863G>A p.L621= | Silent (SNP) | VAF 20/470 reads (4%) | catalogued as COSV99449411; called by muse, mutect2
- VWA3B | c.99C>T p.L33= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as rs368502038; called by muse, mutect2, varscan2
- ZDHHC22 | c.585C>T p.I195= | Silent (SNP) | VAF 114/232 reads (49%) | catalogued as rs755735897, COSV100083829; called by muse, mutect2, varscan2
- ZNF534 | c.642T>C p.L214= (on ENST00000332323 / NM_001143939.3; = p.L201= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/694 reads (8%) | catalogued as rs776411281; called by mutect2, varscan2
- ZNF836 | c.1014C>T p.T338= | Silent (SNP) | VAF 24/775 reads (3%) | catalogued as COSV100441214; called by muse, mutect2
- ZSCAN22 | c.999C>T p.F333= | Silent (SNP) | VAF 53/392 reads (14%) | catalogued as rs556783304, COSV100308484; called by muse, varscan2
- AL109984.1 | n.186+5418G>A | Intron (SNP) | VAF 22/143 reads (15%) | catalogued as rs1417208653, COSV100801986; called by muse, varscan2
- AP000769.3 | chr11:65501567 del AT | 5'Flank (DEL) | VAF 102/212 reads (48%) | called by mutect2, pindel, varscan2
- NCL | c.1832+134A>C | Intron (SNP) | VAF 6/28 reads (21%) | called by mutect2, varscan2
- SKP1 | c.*2A>G | 3'UTR (SNP) | VAF 184/584 reads (32%) | catalogued as COSV100104639; called by muse, mutect2, varscan2
